Somatic mutation profile of tumor specimen SM-JU34N (aliquot 7316UP-603) from CPTAC case C207624, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen SM-JU34N: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bc1f5a8-75f7-4db6-ab0a-f1fd2f474665.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105207 (Blood Derived Normal), aliquot 7316UP-603-1105207; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1435e0c9-2a39-419c-9728-75a541631873

The open-access MAF lists 68 somatic variants for this specimen: 40 protein-altering or splice-affecting, 18 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 18, Nonsense Mutation 4, Intron 4, 5'UTR 3, RNA 2, Frame Shift Del 2, Splice Site 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INPPL1 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs397514510, CM130299; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL8A2 | c.1917G>C p.K639N | Missense Mutation (SNP) | VAF 294/936 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57441316; called by muse, mutect2, varscan2
- DBH | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 156/421 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs766166337, COSV55039535; called by muse, mutect2, varscan2
- DMWD | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV54289226; called by muse, mutect2, varscan2
- FNDC1 | c.5485G>T p.E1829* | Nonsense Mutation (SNP) | VAF 101/151 reads (67%) | catalogued as COSV51938765; called by muse, mutect2, varscan2
- HABP2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 112/163 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs776334292, COSV63636120; called by muse, mutect2, varscan2
- HR | c.3349G>A p.V1117M | Missense Mutation (SNP) | VAF 245/413 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747696916; called by muse, mutect2, varscan2
- MYEF2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99981562; called by muse, mutect2, varscan2
- NF1 | c.3822_3823del p.F1275Pfs*8 | Frame Shift Del (DEL) | VAF 90/194 reads (46%) | catalogued as rs1555615472; called by pindel, varscan2
- NFATC2 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.77); catalogued as rs1568726068, COSV65353091; called by muse, mutect2, varscan2
- PAX1 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV68272913; called by muse, mutect2, varscan2
- PCDH19 | c.2258_2261del p.T753Rfs*4 | Frame Shift Del (DEL) | VAF 99/311 reads (32%) | catalogued as rs1356044384; called by pindel, varscan2
- PKD1 | c.4073C>T p.A1358V | Missense Mutation (SNP) | VAF 301/747 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs376991027; called by muse, mutect2, varscan2
- PPARA | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 150/232 reads (65%) | catalogued as rs764930526, COSV53077323; called by muse, mutect2, varscan2
- PTPRQ | c.4735C>T p.P1579S (on ENST00000616559; = p.P1537S on NM_001145026.2) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs746711598; called by muse, varscan2
- SP3 | c.1778A>G p.K593R | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.235); catalogued as rs781269537; called by muse, mutect2, varscan2
- SRD5A2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as COSV51873520; called by muse, mutect2, varscan2
- TACR3 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 168/378 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs202051644; called by muse, mutect2, varscan2
- TRIM69 | c.1033G>A p.V345I (on ENST00000329464 / NM_182985.5; = p.V186I on NM_080745.5) | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.906); catalogued as rs778647787, COSV57802812; called by muse, mutect2, varscan2
- WDFY4 | c.2996C>T p.A999V | Missense Mutation (SNP) | VAF 119/304 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs568244681, COSV57444519; called by muse, mutect2, varscan2
- ADGRA3 | c.1216T>C p.W406R | Missense Mutation (SNP) | VAF 110/376 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID4B | c.1589A>G p.E530G | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAMKK2 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DSPP | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- FGA | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 124/419 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GABPB2 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- HMCN1 | c.15505G>T p.G5169* | Nonsense Mutation (SNP) | VAF 178/456 reads (39%) | called by muse, mutect2, varscan2
- IGFLR1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC38 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 175/462 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- MUC4 | c.9853G>T p.D3285Y | Missense Mutation (SNP) | VAF 116/432 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.866); called by muse, varscan2
- MYO10 | c.5019C>G p.Y1673* | Nonsense Mutation (SNP) | VAF 59/214 reads (28%) | called by muse, mutect2, varscan2
- POM121L12 | c.530C>A p.T177N | Missense Mutation (SNP) | VAF 81/247 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PPIE | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRDM9 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 135/564 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- SLC22A4 | c.9C>G p.D3E | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SLC35A2 | c.326A>T p.Y109F | Missense Mutation (SNP) | VAF 168/427 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SPAG17 | c.3236A>T p.K1079M | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- STXBP1 | c.1548-1G>A p.X516_splice | Splice Site (SNP) | VAF 149/410 reads (36%) | called by muse, mutect2, varscan2
- TP53 | c.1025dup p.E343Rfs*4 | Frame Shift Ins (INS) | VAF 196/354 reads (55%) | called by mutect2, pindel, varscan2
- TTN | c.64370G>C p.R21457T (on ENST00000591111; = p.R14033T on NM_003319.4) | Missense Mutation (SNP) | VAF 13/106 reads (12%) | PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ACVR1B | c.393C>T p.I131= | Silent (SNP) | VAF 142/290 reads (49%) | catalogued as rs1055232752, COSV57779881; called by muse, mutect2, varscan2
- ARMCX2 | c.639G>A p.S213= | Silent (SNP) | VAF 130/354 reads (37%) | catalogued as rs200974747; called by muse, mutect2, varscan2
- CCDC30 | c.2442A>G p.T814= (on ENST00000340612; = p.T771= on NM_001080850.3) | Silent (SNP) | VAF 70/203 reads (34%) | called by muse, mutect2, varscan2
- CHRNA4 | c.46C>T p.L16= | Silent (SNP) | VAF 182/596 reads (31%) | catalogued as COSV64717727; called by muse, mutect2, varscan2
- CLDN11 | c.435C>T p.A145= | Silent (SNP) | VAF 53/351 reads (15%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.849C>T p.D283= | Silent (SNP) | VAF 87/196 reads (44%) | catalogued as rs1054703704, COSV63583731; called by muse, mutect2, varscan2
- DIP2C | c.3174T>C p.R1058= | Silent (SNP) | VAF 72/198 reads (36%) | called by muse, mutect2, varscan2
- FAM135B | c.2742T>C p.G914= | Silent (SNP) | VAF 73/127 reads (57%) | called by muse, mutect2, varscan2
- INPP5D | c.2382T>C p.P794= (on ENST00000445964 / NM_001017915.3; = p.P793= on NM_005541.5) | Silent (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2
- MMGT1 | c.267C>A p.S89= | Silent (SNP) | VAF 55/143 reads (38%) | called by muse, mutect2, varscan2
- OR4K2 | c.228C>T p.F76= | Silent (SNP) | VAF 52/86 reads (60%) | catalogued as rs370258306, COSV53848469; called by muse, mutect2, varscan2
- OSCP1 | c.15G>A p.T5= | Silent (SNP) | VAF 62/142 reads (44%) | called by muse, mutect2, varscan2
- PCDHB1 | c.1329C>G p.S443= | Silent (SNP) | VAF 31/173 reads (18%) | catalogued as COSV60629356; called by muse, mutect2, varscan2
- RBP4 | c.525G>A p.E175= | Silent (SNP) | VAF 24/275 reads (9%) | called by muse, mutect2
- RECQL4 | c.2286G>A p.Q762= | Silent (SNP) | VAF 44/439 reads (10%) | catalogued as COSV99468277; called by muse, mutect2
- WWP2 | c.2382G>A p.L794= | Silent (SNP) | VAF 65/190 reads (34%) | called by muse, mutect2, varscan2
- YWHAB | c.639T>C p.Y213= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs755545276; called by muse, mutect2, varscan2
- ZNF469 | c.10575G>A p.P3525= (on ENST00000437464; = p.P3553= on NM_001367624.2) | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs957291420; called by muse, mutect2, varscan2
- CELF6 | c.-46C>T | 5'UTR (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- FAM83A | c.-265C>G | 5'UTR (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- FST | c.953-38G>A | Intron (SNP) | VAF 116/256 reads (45%) | catalogued as rs1452197327, COSV56816565, COSV99887522; called by muse, mutect2, varscan2
- NR5A2 | c.1110+8717G>T | Intron (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- OR6W1P | n.514C>T | RNA (SNP) | VAF 63/201 reads (31%) | catalogued as rs752645238; called by muse, mutect2, varscan2
- PAX4 | c.145-32C>G | Intron (SNP) | VAF 17/366 reads (5%) | called by muse, mutect2
- RGS14 | c.-87C>T | 5'UTR (SNP) | VAF 9/14 reads (64%) | catalogued as rs1236822655; called by muse, varscan2
- RN7SL319P | chr15:75786573 C>T | 3'Flank (SNP) | VAF 139/310 reads (45%) | catalogued as rs759807062; called by muse, mutect2, varscan2
- SSPOP | n.6318C>T | RNA (SNP) | VAF 18/123 reads (15%) | catalogued as COSV50487378; called by muse, mutect2, varscan2
- TTN | c.32876-34G>A | Intron (SNP) | VAF 77/247 reads (31%) | catalogued as rs527456592, COSV59897810; called by muse, mutect2, varscan2
